Gene-level copy-number profile of tumor specimen TCGA-DX-AB2W-01A from TCGA case TCGA-DX-AB2W, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 62.8 years (22,951 days).
Specimen TCGA-DX-AB2W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.f881ef1d-d495-4bce-975a-f468c2c31e9b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50f283f9-d726-42a4-b1a7-f0d28e5a9259

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 6,192; copy number 2: 26,870; copy number 3: 14,430; copy number 4: 8,593; copy number 5: 2,083; copy number 6: 974; copy number 7: 340; copy number 8: 138; copy number 9: 37; copy number 10: 40; copy number 11: 8; copy number 15: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2W-01A-11D-A38Y-01): tumor purity 0.54, ploidy 2.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:115,802,363–117,139,389, 1 gene (within-gene range 0–1): LSAMP.
- chr3:116,360,024–117,997,592, 15 genes (within-gene range 0–1): LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8, RNU6-1200P, AC092691.1, AC092691.2, LINC02024.
- chr3:118,004,819–120,094,994, 31 genes (within-gene range 0–1): AC068633.1, AC068633.2, IGSF11, IGSF11-AS1, TEX55, AC083800.1, UPK1B, B4GALT4, B4GALT4-AS1, ARHGAP31, RPS26P21, ARHGAP31-AS1, RNU6-1127P, TMEM39A, POGLUT1, AC073352.1, TIMMDC1, CD80, AC073352.2, ADPRH, PLA1A, RPL10P7, POPDC2, COX17, AC023494.1, CFAP91, AC069444.2, AC069444.1, NR1I2, PHBP8, GSK3B.
- chr11:127,657,568–128,686,922, 8 genes: AP003532.1, DNAJB6P1, LINC02725, LINC02098, ETS1, MIR6090, ETS1-AS1, AP001122.1.
- chr11:128,691,672–128,696,023, 1 gene: SENCR.
- chr11:130,226,677–131,350,917, 21 genes: ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, AP003486.2, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2.
- chr11:131,385,249–131,540,867, 2 genes (within-gene range 0–2): RNU6ATAC12P, AP003025.1.
- chr11:132,284,302–133,532,519, 6 genes (within-gene range 0–2): NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2.
- chr11:133,297,189–133,302,634, 1 gene: AP003972.1.
- chr16:89,267,630–89,490,561, 1 gene (within-gene range 0–1): ANKRD11.
- chr16:89,420,075–89,459,437, 4 genes: AC092120.1, AC092120.3, RNU6-430P, AC092120.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,619 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:103,874,310–108,217,886, 81 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:124,025,287–126,902,097, 19 genes, copy number 5 (within-gene range 3–5): CNTNAP5, MTND5P22, AC019159.2, AC019159.1, RNA5SP102, RNU6-259P, AC097499.2, LINC01889, AC097499.1, LINC01941, AC142116.2, AC023347.1, SLC6A14P3, YWHAZP2, AC013474.2, GYPC, AC013474.1, RNU6-675P, TEX51.
- chr2:131,821,987–139,511,555, 98 genes, copy number 5–6 (broad region; genes not listed).
- chr2:162,142,882–164,352,223, 14 genes, copy number 5: GCG, AC007750.1, FAP, IFIH1, GCA, KCNH7, RNA5SP109, KCNH7-AS1, RPL7P61, RNU6-627P, FIGN, AC016766.1, PRPS1P1, CYP2C56P.
- chr2:167,954,020–169,031,324, 11 genes, copy number 5 (within-gene range 2–5): STK39, PHF5GP, RN7SL813P, CERS6, MIR4774, RNU6-766P, CERS6-AS1, NOSTRIN, SPC25, G6PC2, ABCB11.
- chr3:32,685,145–44,439,946, 223 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:99,215,224–100,456,319, 18 genes, copy number 7: ACTG1P13, AC107297.1, AC078828.1, AC107029.1, AC107029.2, COL8A1, AC069222.1, CMSS1, FILIP1L, MIR3921, AC129803.1, TMEM30CP, DUSP12P1, VTI1BP1, TBC1D23, NIT2, TOMM70, LNP1.
- chr3:160,225,496–164,831,480, 41 genes, copy number 5: C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324.
- chr4:34,657,606–56,603,507, 322 genes, copy number 5–7 (broad region; genes not listed).
- chr5:35,895,689–36,876,700, 23 genes, copy number 8–15: AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT.
- chr5:42,423,439–45,895,970, 61 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr7:54,542,325–55,211,628, 12 genes, copy number 5: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr8:36,378,069–40,901,854, 98 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:41,490,396–50,860,062, 149 genes, copy number 5 (broad region; genes not listed).
- chr11:34,478,791–60,078,401, 579 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:98,565,074–104,609,498, 73 genes, copy number 6–8 (broad region; genes not listed).
- chr12:9,448,295–14,502,935, 161 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:15,322,257–38,329,721, 335 genes, copy number 5–10 (broad region; genes not listed).
- chr12:41,188,320–41,932,592, 8 genes, copy number 5 (within-gene range 4–5): PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1.
- chr15:31,475,398–31,870,789, 3 genes, copy number 5 (within-gene range 2–5): OTUD7A, DEPDC1P1, AC026951.1.
- chr15:46,099,193–46,661,103, 7 genes, copy number 5: AC068714.1, AC091074.3, MTND5P40, AC091074.1, AC091074.2, AC012405.1, RNU6-1014P.
- chr15:48,971,803–50,546,708, 37 genes, copy number 5: KRT8P24, SECISBP2L, Y_RNA, RN7SL577P, AC013452.2, COPS2, Y_RNA, GALK2, NDUFAF4P1, MIR4716, AC013452.1, RN7SL307P, FAM227B, AC022306.2, AC022306.3, AC022306.1, FGF7, DTWD1, AC025040.2, ATP8B4, AC025040.1, RNA5SP394, SLC27A2, Y_RNA, HDC, RN7SL494P, GABPB1, RNU6-94P, GABPB1-IT1, GABPB1-AS1, AC022087.1, MIR4712, AHCYP7, USP8, RNA5SP395, AC012170.1, USP50.
- chr15:50,908,672–51,751,585, 21 genes, copy number 5 (within-gene range 2–5): AP4E1, DCAF13P3, MIR4713HG, TNFAIP8L3, AC073964.1, CYP19A1, MIR4713, AC020891.3, MIR7973-2, MIR7973-1, AC020891.2, GLDN, AC020891.4, AC020891.1, AC066613.2, DMXL2, AC066613.1, SCG3, AC020892.1, AC020892.2, LYSMD2.
- chr15:52,505,191–53,984,010, 18 genes, copy number 5–6: EEF1B2P1, ARPP19, AC025917.1, FAM214A, AC009754.1, AC009754.2, ONECUT1, AC016044.1, RPSAP55, EEF1A1P22, LINC02490, AC066614.1, WDR72, RNU2-53P, RNU6-449P, AC084759.1, AC084759.3, AC084759.2.
- chr15:55,056,723–71,783,383, 387 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr15:94,841,059–95,507,865, 10 genes, copy number 5 (within-gene range 4–5): AC087633.2, AC107976.1, AC087633.1, AC087636.1, LINC01197, AC104260.1, AC104260.2, AC104260.3, LINC00924, AC027013.1.
- chr15:101,043,716–101,295,282, 8 genes, copy number 6: AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1.
- chr15:101,295,419–101,337,428, 3 genes, copy number 6: AC023024.1, AC023024.2, PCSK6-AS1.
- chr18:4,264,602–6,108,382, 25 genes, copy number 6–9: DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3.
- chr18:5,956,101–6,017,839, 2 genes, copy number 9: AP001021.2, RNU5F-3P.
- chr19:3,224,661–3,593,541, 18 genes, copy number 6: CELF5, AC010649.1, NFIC, AC007792.1, AC005514.1, SMIM24, AC005551.1, DOHH, FZR1, AC005787.1, MFSD12, C19orf71, AC005786.3, AC005786.2, AC005786.4, AC005786.1, HMG20B, GIPC3.
- chr19:5,691,834–8,005,659, 130 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:760,080–11,687,323, 235 genes, copy number 5–7 (broad region; genes not listed).
- chr20:46,997,596–54,651,169, 151 genes, copy number 6 (broad region; genes not listed).
- chr20:55,607,852–57,620,576, 48 genes, copy number 5 (within-gene range 3–5): AL109829.1, AL109828.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1.
- chr20:58,863,528–59,469,853, 17 genes, copy number 6 (within-gene range 3–6): AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2.
- chr21:20,651,450–21,797,415, 8 genes, copy number 8: LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425.
- chr21:24,306,939–25,135,247, 9 genes, copy number 8–11 (within-gene range 3–11): LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1.
- chr21:26,317,390–33,071,104, 146 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr21:33,229,901–33,310,187, 4 genes, copy number 8: IFNAR2, AP000295.1, IL10RB-DT, IL10RB.

Autosomal genes at a single copy (total copy number 1): 4,836. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
